Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4304, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4304-01A (Primary Tumor).

■

Diagnosis:

Resection material from the region of a gastroenteral anastomosis with the inclusion of a moderately differentiated adenocarcinoma of the stomach located in the region of the heart, measuring a maximum diameter of 4.8 cm and showing polypous growth, with infiltration of the tunica muscularis propria. Tumor-free esophageal and tumor-free small intestine resection margins. Tumor-free regional lymph nodes. Medium-grade chronic, slightly active *Helicobacter pylori*-associated gastritis with partial atrophy of the glandular tissue and also multiple so-called lipid islands.

Tumor stage: pT2a pN0 (0/18) pMX; ■

Source: NCI Genomic Data Commons file 31d5cb07-47be-4f44-8f94-506950742962 (TCGA-CG-4304.377B1E60-C4E1-4C6A-B2EA-B22345FEEB02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).